Somatic mutation profile of tumor specimen MP2PRT-PAPDDM-TMP1-A (aliquot MP2PRT-PAPDDM-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPDDM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 3.6 years (1,302 days).
Specimen MP2PRT-PAPDDM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c76e959-333b-4047-8d5d-58f86ae90d1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPDDM-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPDDM-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a1ba707-eba2-4224-af4e-fc44c8cb2449

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL16 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 111/285 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770332586; called by muse, mutect2, varscan2
- KIAA1549L | c.4642G>A p.D1548N (on ENST00000321505; = p.D1845N on NM_012194.3) | Missense Mutation (SNP) | VAF 176/411 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs529048568, COSV100382304; called by muse, mutect2, varscan2
- SLIT3 | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 131/297 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60609179; called by muse, mutect2, varscan2
- IGHV4-59 | c.349_350insGCCCTCGAGAT | In Frame Ins (INS) | VAF 24/336 reads (7%) | called by mutect2, pindel
- KIAA1109 | c.9904T>G p.L3302V | Missense Mutation (SNP) | VAF 92/331 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KIAA1109 | c.9905T>G p.L3302* | Nonsense Mutation (SNP) | VAF 92/334 reads (28%) | called by muse, mutect2, varscan2
- STIM2 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 141/335 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
